FM case AD12818 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Specialized Gonadal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/46dcfcf3-f18d-4244-8f7f-0fd6a69bb23e

Female, 34.3 years: Granulosa cell tumor, NOS (ICD-O-3 8620/1) of the ovary; primary biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
